Surgical pathology report (de-identified scan), TCGA case TCGA-75-6207, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-75-6207-01A (Primary Tumor).

[page 1 of 2]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).													
Sample Collection Details									Histology and staging				
Sample Number	Sample Type	Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)	Tumour Size (cm)	Histology	
	TUMOUR	FF							RESECT	RLNOS	3.10	03	
	BUFFY	FF							RESECT	RLNOS	3.10	03	

[page 2 of 2]
Grade/ Differentiation	Pathological T	Pathological N	Clinical M	VALCSG Stage	Histology Comments	Slide URL					
III	T2,NOS	N2	M0		Tumour involves both upper and middle right lobes.						
III	T2,NOS	N2	M0		Tumour involves both upper and middle right lobes.						

Source: NCI Genomic Data Commons file aab974b2-487b-4cee-a42c-bffb71cf2475 (TCGA-75-6207.46E1C8E2-5603-41C4-8B84-552BA6537FF1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).